TARGET case TARGET-40-0A4HY5 — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of other and unspecified sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2ac845dc-8544-5809-ae2c-68ab94a24d7c

Demographics
Sex at birth: male; Age at index: 19 years; Vital status: Dead; Days to death: 290 days.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C41.4; Tissue or organ of origin: Pelvic bones, sacrum, coccyx and associated joints; Classification of tumor: primary; Age at diagnosis: 19.9 years (7,264 days); Year of diagnosis: 2004; Metastasis at diagnosis: Metastasis, NOS; Days to last follow up: 290 days; Sites of involvement: Lung, NOS.
   Pathology details: Necrosis percent: 50.
   Treatment given: Protocol identifier: IHRT.
   Treatment given: Therapeutic agents: Doxorubicin.
   Treatment given: Therapeutic agents: Methotrexate.
   Treatment given: Therapeutic agents: Platinum.

Follow-up (2 entries)
- Days to follow up: 218 days; Progression or recurrence: Yes; Days to progression: 218 days; Days to first event: 218 days; First event: Relapse.
- Days to follow up: 290 days; Year of follow up: 2005.

Biospecimens (2 samples)
- Sample TARGET-40-0A4HY5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-0A4HY5-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_20230709.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 290
- Disease at diagnosis: Metastatic
- Metastasis site: Lung only
- Primary tumor site: Leg/foot
- Specific tumor site: Pelvis
- Specific tumor region: Other, Posterior
- Definitive Surgery: Limb sparing
- Primary site progression: No
- Site of initial relapse: Non-bone, non-lung
- Histologic response: Stage 1/2 (0-90 % necrosis)
- Therapy: Adria/Plat/MTX
